Gene-level copy-number profile of tumor specimen TCGA-CN-5367-01A from TCGA case TCGA-CN-5367, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 60.9 years (22,246 days).
Specimen TCGA-CN-5367-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.d06ac510-0c31-4e34-8d18-d0d5b958b945.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-5367-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0b129549-3e0a-48fa-ac4d-4812adb2c965

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 99; copy number 1: 7,522; copy number 2: 39,966; copy number 3: 10,864; copy number 4: 688; copy number 5: 67; copy number 6: 83; copy number 7: 16; copy number 8: 86; copy number 9: 103; copy number 10: 17; copy number 12: 63; copy number 14: 11; copy number 15: 7; copy number 17: 28; copy number 19: 40; copy number 20: 23; copy number 21: 1; copy number 24: 28; copy number 25: 7; copy number 28: 24; copy number 29: 30; copy number 32: 25; copy number 37: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-5367-01A-01D-1432-01): tumor purity 0.55, ploidy 2.1, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 99 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:10,532,145–12,823,060, 18 genes: AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL355672.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L.
- chr9:19,705,338–23,682,662, 81 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 677 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:94,207,611–94,668,227, 5 genes, copy number 6 (within-gene range 2–6): SMARCAD1, HPGDS, AC109925.1, RPL35AP11, PDLIM5.
- chr4:146,175,703–149,024,624, 37 genes, copy number 5 (within-gene range 1–5): LSM6, AC097372.2, REELD1, AC097372.3, AC097372.1, SLC10A7, MIR7849, RNU1-44P, POU4F2, TTC29, AC092435.2, AC092435.1, AC092435.3, AC092435.4, AC097450.1, MIR548G, AC010683.1, PRMT5P1, EDNRA, AC093908.1, GTF2F2P1, LINC02507, AC093835.1, TMEM184C, PRMT9, ARHGAP10, RNA5SP165, MIR4799, RN7SL254P, AC115621.1, NR3C2, AC069272.1, AC002460.2, ASS1P8, RNA5SP166, AC108935.1, ATP5MGP4.
- chr4:187,613,708–190,092,279, 52 genes, copy number 5–10 (within-gene range 1–10): AC097521.1, ADAM20P3, AC108073.3, AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434, AC093789.1, ICE2P1, LINC01060, AC093909.3, AC093909.5, RNU7-192P, AC093909.1, AC093909.6, AC093909.2, LINC02508, AC093909.4, AC122138.1, AC107391.1, AC105924.1, HSP90AA4P, LINC01262, AF250324.1, RNU1-51P, FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr7:70,972–989,640, 28 genes, copy number 5–6: AC093627.1, AC093627.6, AC093627.22, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC188616.1, AC226118.1, AC188617.1, AC188617.2, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1.
- chr7:1,022,933–1,023,026, 1 gene, copy number 6: MIR339.
- chr7:17,962,079–18,000,879, 2 genes, copy number 8: RNMTL1P2, AC080080.2.
- chr7:38,256,337–38,318,861, 10 genes, copy number 8 (within-gene range 2–8): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr7:64,307,459–65,006,743, 34 genes, copy number 6 (within-gene range 2–6): ZNF736, TRIM60P18, AC073270.2, AC022202.1, YWHAEP1, VN1R40P, ZNF680P1, HNRNPCP7, ZNF680, BNIP3P42, AC016769.3, AC016769.1, AC016769.2, AC016769.4, AC016769.5, AC016769.6, ZNF107, BNIP3P11, MIR6839, AC091799.1, AC073349.3, ZNF138, AC073349.4, AC073349.2, SEPHS1P1, EEF1DP4, AC073349.5, ZNF273, AC073349.1, VN1R42P, MTDHP1, AC073210.3, ZNF117, ERV3-1.
- chr8:71,155,454–71,204,223, 1 gene, copy number 8: AC022858.1.
- chr9:13,386,130–17,503,923, 51 genes, copy number 9–24 (within-gene range 1–24): AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B, RPL7P33, SNAPC3, RNU6-319P, PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P, CCDC171, HMGN2P16, RNU6-14P, C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1, CNTLN.
- chr11:67,006,778–68,130,518, 73 genes, copy number 8 (broad region; genes not listed).
- chr11:68,612,899–74,311,640, 192 genes, copy number 7–28 (within-gene range 1–28) (broad region; genes not listed).
- chr11:100,336,856–102,705,769, 36 genes, copy number 20–32: RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27.
- chr11:105,609,994–107,177,530, 19 genes, copy number 21–37: GRIA4, HSPD1P13, RNU4-55P, RNU6-277P, AP000813.1, MSANTD4, KBTBD3, AASDHPPT, AP001001.1, AP001001.2, LINC02719, AP002001.3, AP002001.1, AP002001.2, AP003173.1, GUCY1A2, AP001282.2, AP001282.1, ASS1P13.
- chr14:21,903,077–22,506,702, 80 genes, copy number 6–12 (broad region; genes not listed).
- chr18:2,847,006–5,630,700, 56 genes, copy number 15–29: EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66, DLGAP1-AS5, AP005208.1, ELOCP27, AP005203.1, PPIAP14, LINC01892, BOD1P2, AKAIN1, AP005380.1, AP001496.4, AP001496.2, LINC00526, LINC00667, AP001496.3, ZBTB14, AP001496.1, AP005671.1, EPB41L3, AP005059.2, AP005059.1.

Autosomal genes at a single copy (total copy number 1): 7,522. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
